CCDI case PBBTDX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/674d0cec-816c-4a77-a9f2-e605cc6be0fc

Demographics
Sex at birth: male.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.7 years (3,165 days).

Biospecimens (3 samples)
- Sample 0DG9FS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DG9FY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DG9KP: Tissue type: Tumor; Specimen type: Solid Tissue.
